Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2GN, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2GN-06A (Metastatic).

DOB/Age/Sex:

Location:

Requested by:

Requested on:

Specimen Rcvd:

Accession No.:

Copies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

CLINICAL DETAILS

Recurrent melanoma. R chest wall (suture superior). Histopath.

MACROSCOPIC DESCRIPTION

(Dr

"RIGHT CHEST WALL LESION STITCH SUPERIOR". An orientated ellipse of skin, 70x48x17mm. There is one stitch at midway of one long edge indicating superior and designating 12 o'clock. The skin surface appears unremarkable. 12 o'clock half inked blue and 6 o'clock half inked black. Sectioning shows 2 tan subcutaneous nodules, 15mm across each. The first nodule is abutting the deep margin. Representative section embedded in one block. Tissue taken for tumour banking from first (largest) nodule (4x 3mm pieces -

A&B. First nodule

B&C. Second nodule

1CD-0-3

Melanoma, NOS 8720/3

Site: Subcutaneous, chest wall
C49.3

hw 4/10/11

MICROSCOPIC REPORT

"RIGHT CHEST WALL LESION STITCH SUPERIOR".

The sections show skin to the level of subcutaneous tissue. Sections of both of the nodules, which lie within the subcutis, show that they are well circumscribed and partially pseudoencapsulated cellular nodules composed of malignant epithelioid and spindled cells. The cells have high nuclear: cytoplasmic ratio, large, pleomorphic oval nuclei containing prominent nucleoli, and with moderate amounts of amphophilic cytoplasm with focal intracytoplasmic brown pigment. Numerous mitotic figures and apoptotic bodies are seen. There are areas of necrosis. The largest nodule lies 0.5mm from the deep margin and 8mm from the 12 o'clock margin, and the second nodule lies 7mm from 6 o'clock. The tumour cells show patchy strong nuclear staining for S100 and are positive for HMB45 and Melan A. The combination of features are consistent with melanoma.

SUMMARY

Skin, right chest wall - MELANOMA, Please see report.

REPORTED BY: Dr.

hw 4/23/11

Source: NCI Genomic Data Commons file 62ab1be0-29f1-45aa-abe2-bfbbdef672b7 (TCGA-EE-A2GN.AC0FD9F4-3181-47B7-A454-AE3E5C7D95B6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).